Somatic mutation profile of tumor specimen MP2PRT-PANTXA-TMP1-A (aliquot MP2PRT-PANTXA-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANTXA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,357 days).
Specimen MP2PRT-PANTXA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72bcd568-a91d-4d2d-af84-7a2ffcd349bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANTXA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANTXA-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78af1df3-c081-47f6-8d56-7794cc26641f

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 55/393 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- MRGPRX2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 32/635 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs751093012; called by muse, mutect2
- RASSF9 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 47/327 reads (14%) | catalogued as rs1053694318, COSV63432565; called by muse, mutect2, varscan2
- HSPG2 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 61/468 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- FBN2 | c.4422C>T p.C1474= | Silent (SNP) | VAF 85/419 reads (20%) | catalogued as rs371629482, COSV52500874, COSV99330174; called by muse, mutect2, varscan2
- GPATCH8 | c.3498G>A p.L1166= | Silent (SNP) | VAF 60/433 reads (14%) | catalogued as COSV59193272; called by muse, mutect2, varscan2
- KCNN3 | c.1278C>T p.S426= | Silent (SNP) | VAF 126/537 reads (23%) | called by muse, mutect2, varscan2
- ZNF462 | c.3477G>A p.G1159= | Silent (SNP) | VAF 75/508 reads (15%) | catalogued as rs1320524541; called by muse, mutect2, varscan2
- FCRL6 | c.-3C>T | 5'UTR (SNP) | VAF 47/252 reads (19%) | called by muse, mutect2, varscan2
